Somatic mutation profile of tumor specimen BA2901D (aliquot aq-BA2901D) from BEATAML1.0 case 2529, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.2 years (24,894 days).
Specimen BA2901D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2122ffc-0ec2-42ac-8ba0-db4ea847f514.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2432D (Solid Tissue Normal), aliquot aq-BA2432D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67b1200e-4b50-4436-bd1a-3a73f6ba90ec

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL14A1 | c.5312C>A p.A1771D | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.249); catalogued as COSV52855156; called by muse, mutect2
- COL12A1 | c.1473G>T p.E491D | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KLK8 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NMNAT2 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.983); called by muse, mutect2
- NR4A3 | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.015); called by muse, mutect2
- NTN3 | c.1250C>A p.P417Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- PDZD8 | c.8T>G p.L3R | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2
- SETD1A | c.4558C>A p.Q1520K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.192); called by muse, mutect2
- ANO8 | c.66G>T p.P22= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- UBE4A | c.2934A>G p.Q978= (on ENST00000252108 / NM_001204077.2; = p.Q985= on NM_004788.4) | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as rs782259280; called by muse, mutect2, varscan2
- HDGFL3 | c.607-5291G>T | Intron (SNP) | VAF 4/34 reads (12%) | catalogued as rs1032477934; called by muse, mutect2
